Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A43X, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A43X-01A (Primary Tumor).

[page 1 of 4]
Gender: Male

DOB:

Race: White

Report Date:

Pathology Report:

1CD-0-3

carcinoma, papillary urothelial 8130/3
cQcF site: bladder, wall, posterior c67.4
Path bladder, vas c67.9

h
9/24/12

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Left pelvic lymph nodes:

- Eight lymph nodes (0/8), no tumor.

B. Right pelvic lymph nodes:

- Twenty lymph nodes (0/20), no tumor.

C. Bladder, prostate, seminal vesicles, vas deferens:

- Papillary urothelial carcinoma of the bladder.

- One lymph node (0/1), no tumor.

- Prostatic hyperplasia, no tumor.

- Seminal vesicles and vas deferens, no tumor.

- Focal chronic and granulomatous inflammation consistent with treatment effect.

D. Distal right ureter:

- Ureteral segment, no tumor.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type:

Papillary urothelial carcinoma

2. Grade of tumor:

High grade

3. Depth of invasion:

Lamina propria

Muscularis propria: Inner half with focus of lymphovascular invasion (C25)

4. Tumor distribution:

Multifocal (confluent), 8.5 cm largest size

Dome

Right lateral wall

Left lateral wall

Trigone

Anterior wall

Posterior wall

5. Ureteral margins:

HIIPAA Discrepancy		X

hml
8/30/12

[page 2 of 4]
Negative

6. Distal urethral margin:

Negative

7. Soft tissue margin or serosa:

Negative

8. Lymph nodes:

0/28

9. pTNM:

ypT2a, N0, MX

this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

xxx

☐ M.D.

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, ☐ MD

Electronically Signed Out by ☐, M.D.

Clinical History:

The patient is an -year-old male with high grade urothelial carcinoma of the bladder undergoing cystoprostatectomy.

Specimens Received:

A: Left pelvic lymph nodes

B: Right pelvic lymph nodes

C: Bladder, prostate, seminal vesicles, vas deferens

D: Distal right ureter

Gross Description:

The specimen is received in four containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "1. Left pelvic lymph nodes". Received fresh and placed in formalin is a 4.5 x 2.5 x 1.5 cm aggregate of lobulated yellow fibrofatty tissue. The specimen is dissected for lymph nodes to reveal 8 apparent lymph nodes ranging from 0.5-3.5 cm in greatest dimension. All apparent lymph nodes are submitted as follows:

A1: 1 candidate lymph node, serially sectioned

A2: 3 candidate lymph nodes

A3: 3 candidate lymph nodes

A4: 1 candidate lymph node, bisected

[page 3 of 4]
B. The second container is additionally identified as, "2. Right pelvic lymph nodes". Received fresh and placed in formalin is a 6.5 x 4.0 x 1.5 cm aggregate of lobulated yellow fibrofatty tissue. The specimen is dissected for lymph nodes to reveal 20 apparent lymph nodes ranging from 0.3-3.0 cm in greatest dimension. All apparent lymph nodes are submitted as follows:

B1: 6 lymph node candidates

B2: 4 lymph node candidates

B3: 4 lymph node candidates

B4: 1 lymph node candidate, bisected

B5: 1 lymph node candidate, bisected

B6: 1 lymph node candidate, bisected

B7: 3 lymph node candidates

C. The third container is additionally identified as, "3. Bladder, prostate, seminal vesicles, vas deferens". Received fresh and placed in formalin is an 18.0 x 11.5 x 7.5 cm cystoprostatectomy specimen with attached mesenteric fat. The bladder measures 8.5 x 8.5 x 7.0 cm. The right ureteral stump measures 0.5 cm and the left 1.0 cm, and both demonstrate patent lumina. The prostate measures 4.8 x 4.0 x 3.6 cm. The right seminal vesicle measures 3.0 x 2.5 x 0.6 cm and the right vas deferens 3.0 cm. The left seminal vesicle measures 3.0 x 2.2 x 0.6 cm and the left vas deferens 7.0 cm. The right half of the prostate is inked blue and the left half is inked black, and the outside of the bladder is inked black. The prostate is opened anteriorly along the urethra and continued superiorly through the bladder in a Y-shaped incision. The prostate is serially sectioned from apex to base to reveal bulging, yellow to tan parenchyma with a 0.4 x 0.3 x 0.3 cm area of induration located on the right prostate posterolaterally. The bladder mass extends near the base of the prostate. The bladder demonstrates a fungating, focally friable, tan-pink mass involving the entire surface of the bladder. Serial sectioning reveals partial tumor invasion into bladder wall to a depth of 1.5 cm, abutting the inked margin in multiple locations of the anterior and posterior bladder. There is no normal mucosa present. The bladder wall thickness is 0.5 cm in areas not grossly involved by the mass. The bilateral ureteral orifices are identified and probe patent.

Photographs are taken. Representative sections are submitted as follows:

C1: Distal urethral margin

C2: Right ureter margin

C3: Left ureter margin

C4: Prostate apex, serially sectioned

C5: Representative sections of right vas deferens and seminal vesicle

C6: Representative sections of left vas deferens and seminal vesicle

C7: Representative section of right prostate through verumontanum

C8: Representative section of left prostate through verumontanum

C9-C10: Representative sections of right prostate above verumontanum in region of induration

C11-C12: Representative sections of left prostate above verumontanum

C13: Right prostate in region of bladder tumor invasion

[page 4 of 4]
C14: Left prostate in region of bladder tumor invasion
C15: Representative section of mass in anterior bladder
C16: Representative section of mass in anterior bladder in region
abutting inked margin
C17-C18: Representative sections of mass in anterior bladder
C19-C21: Representative sections of mass in dome of bladder
C22-C25: Representative sections of mass in posterior bladder

D. The fourth container is additionally identified as, "4. Distal right ureter".
Received fresh and placed in formalin is an unoriented 2.5 cm in length and 0.4
cm in diameter tan, rubbery, tube-like structure with attached adipose tissue.
There is a long suture at one end of the specimen and this end is inked black.
The specimen is serially sectioned and submitted as follows:
D1: Margins
D2: Central sections

[], MD

Source: NCI Genomic Data Commons file 57a4a5c5-120f-475a-b037-fe8c5fae0367 (TCGA-FD-A43X.1DE6AC6C-BA81-4CB1-8595-21D6E9033C7F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).